Gene-level copy-number profile of tumor specimen ALCH-B48L-TTP1-A from ALCHEMIST case ALCH-B48L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.5 years (23,190 days).
Specimen ALCH-B48L-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ce7aa69e-d21e-4461-a3e1-bfd93d6b6930.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B48L-NB2-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/c7f55b3f-c4c9-4604-a8ec-119e61f6ddf7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 519; copy number 1: 660; copy number 2: 894; copy number 3: 14,522; copy number 4: 12,783; copy number 5: 7,859; copy number 6: 12,026; copy number 7: 4,710; copy number 8: 4,512; copy number 9: 217; copy number 10: 125; copy number 11: 3; copy number 12: 48; copy number 14: 23; copy number 15: 7; copy number 23: 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:37,473,330–37,473,977, 1 gene (within-gene range 0–1): AC129908.1.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 9,633 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,246,461–145,918,717, 1,403 genes, copy number 7 (broad region; genes not listed).
- chr2:95,274,449–171,750,158, 1,188 genes, copy number 7–14 (broad region; genes not listed).
- chr2:174,072,447–176,930,090, 70 genes, copy number 7 (broad region; genes not listed).
- chr4:1,056,250–8,516,759, 167 genes, copy number 7 (broad region; genes not listed).
- chr4:10,068,089–39,485,109, 280 genes, copy number 7 (broad region; genes not listed).
- chr4:40,056,850–40,158,252, 1 gene, copy number 7 (within-gene range 5–7): N4BP2.
- chr4:40,142,198–43,972,184, 62 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–41,510,628, 610 genes, copy number 7–9 (broad region; genes not listed).
- chr6:27,060,365–56,954,649, 975 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:37,032–1,269,267, 37 genes, copy number 7: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1.
- chr7:47,740,202–47,948,466, 1 gene, copy number 7 (within-gene range 6–7): PKD1L1.
- chr7:47,795,291–62,275,678, 204 genes, copy number 7 (broad region; genes not listed).
- chr7:77,416,673–97,024,950, 229 genes, copy number 7–11 (broad region; genes not listed).
- chr8:72,947,150–145,066,685, 1,107 genes, copy number 7–15 (broad region; genes not listed).
- chr9:12,685,439–12,710,285, 1 gene, copy number 8 (within-gene range 6–8): TYRP1.
- chr14:20,229,402–20,244,349, 2 genes, copy number 8–11: OR11H7, OR11H4.
- chr14:88,612,431–88,822,151, 3 genes, copy number 8 (within-gene range 3–8): EML5, AL121768.1, RNU4-92P.
- chr15:19,878,555–34,343,136, 491 genes, copy number 8 (broad region; genes not listed).
- chr15:43,106,225–43,185,779, 1 gene, copy number 10 (within-gene range 4–10): AC068724.3.
- chr15:43,115,702–43,221,018, 7 genes, copy number 10: RPS3AP47, TMEM62, SPCS2P1, AC068724.4, AC068724.1, CCNDBP1, EPB42.
- chr16:11,555–352,723, 31 genes, copy number 8: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2, AXIN1.
- chr16:424,243–58,629,885, 1,698 genes, copy number 7–14 (broad region; genes not listed).
- chr16:60,925,733–89,671,272, 742 genes, copy number 7–9 (broad region; genes not listed).
- chr16:89,682,620–89,686,569, 1 gene, copy number 7 (within-gene range 5–7): LINC02166.
- chr19:38,388,421–40,629,818, 122 genes, copy number 7–11 (broad region; genes not listed).
- chr20:16,177,933–20,738,731, 91 genes, copy number 7–9 (broad region; genes not listed).
- chr20:22,547,671–26,134,198, 106 genes, copy number 7–9 (broad region; genes not listed).
- chr22:21,341,595–21,371,945, 3 genes, copy number 14–23: PPP1R26P5, LINC01651, AP000552.1.

Autosomal genes at a single copy (total copy number 1): 660. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
